Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4988, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4988-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

TCGA - BP - 4988

Clinical Diagnosis & History:

year old male with right renal mass.

Specimens Submitted:

1: SP: Kidney, right, nephrectomy

2: SP: Lymph nodes, retroperitoneal, excision

DIAGNOSIS:

1. SP: Kidney, right, nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 2.0 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

See comment

Adrenal Gland:

Not Identified

Lymph Nodes:

Number of nodes examined:1

Free of carcinoma, but involved by chronic lymphocytic leukemia/ small lymphocytic lymphoma

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

Comment: Renal parenchyma shows patchy, dense atypical lymphoid infiltrate, focally extending into perinephric fat, morphologically consistent with chronic lymphocytic leukemia/ small lymphocytic lymphoma

2. SP: Lymph nodes, retroperitoneal, excision:

Malignant lymphoma, morphologically consistent with chronic lymphocytic leukemia/ small lymphocytic lymphoma (see comment)

[page 2 of 3]
No carcinoma seen

Note:

The prior material [REDACTED] has been reviewed. Dr. [REDACTED] has seen the case and concurs.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1). The specimen is received fresh labeled "right kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 912 g in total. The kidney measures 11.0 x 9.0 x 2.0 cm. The attached ureter measures 0.5 cm in length and 0.3 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney is inked black and bivalved to reveal a 2.0 x 1.5 x 1.2 cm well-circumscribed tan-brown, hemorrhagic mass. The mass does not appear to invade into the sinus fat. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.5 cm and the calyces appear normal. A 0.3 cm lymph node is identified in the perinephric fat. The specimen is photographed. Representative sections are submitted for [REDACTED] and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins

T-- tumor

THF-- tumor with hilar fat

TSF -- tumor with sinus fat

TK -- tumor with adjacent kidney

RP -- renal pelvis representative sections

K -- representative sections kidney

BLN -- bisected lymph node

2) The specimen is received in scanty formalin, labeled "retroperitoneal lymph nodes" and consists of multiple fragments of red tan firm tissue measuring in aggregate 7.0 x 5.5 x 5.0 cm. Serial sectioning reveals homogenous tan-white fleshy appearance. The tissue is submitted for [REDACTED]. Representative sections are submitted.

Summary of sections:

U-undesignated

Summary of Sections:

Part 1: SP: Kidney, right, nephrectomy [REDACTED]

Block	Sect. Site	PCs
1	BLN	1
1	K	1
1	RP	1
2	T	2
1	THF	1
1	TK	1
1	TSF	1
1	UVM	1

Part 2: SP: Lymph nodes, retroperitoneal, excision [REDACTED]

[page 3 of 3]
Block
7

Sect. Site
U

PCs
7

Source: NCI Genomic Data Commons file 359db272-1227-4b2e-8ccb-9a74e2024874 (TCGA-BP-4988.6C322DE6-19CD-448F-B0E7-7579F7B6358A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).